Somatic mutation profile of tumor specimen TCGA-OR-A5J7-01A (aliquot TCGA-OR-A5J7-01A-11D-A29I-10) from TCGA case TCGA-OR-A5J7, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 30.9 years (11,279 days).
Specimen TCGA-OR-A5J7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c794109a-d28a-4d0b-b932-4fb8577af2f6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5J7-10A (Blood Derived Normal), aliquot TCGA-OR-A5J7-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bbfe4f0e-cf1f-4760-abce-33e9dc2f3376

The open-access MAF lists 50 somatic variants for this specimen: 42 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 35, Silent 8, Frame Shift Del 3, Nonsense Mutation 2, In Frame Ins 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C19orf44 | c.26G>A p.R9H | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs762331456, COSV99522121; called by muse, mutect2, varscan2
- CECR2 | c.799C>T p.R267* (on ENST00000342247 / NM_001290047.2; = p.R104* on NM_001290046.1) | Nonsense Mutation (SNP) | VAF 34/42 reads (81%) | catalogued as COSV52847607, COSV52850013; called by muse, mutect2, varscan2
- DECR2 | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as rs201409624; called by muse, mutect2, varscan2
- DNAH5 | c.10654G>T p.A3552S | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as COSV54216451; called by muse, mutect2, varscan2
- FBXO8 | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 70/184 reads (38%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.295); catalogued as rs760227265, COSV67031451; called by muse, mutect2, varscan2
- ITIH5 | c.1617C>G p.I539M | Missense Mutation (SNP) | VAF 23/200 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.272); catalogued as COSV53671500; called by muse, mutect2
- OGG1 | c.346G>A p.V116M | Missense Mutation (SNP) | VAF 51/182 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.074); catalogued as rs1426795348; called by muse, mutect2, varscan2
- SLC24A3 | c.1210G>T p.V404L | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs140841773; called by muse, mutect2, varscan2
- SP140 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 80/336 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs1472237343; called by muse, mutect2, varscan2
- XPC | c.1246C>T p.R416C | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.446); catalogued as rs369928352; called by muse, mutect2
- ADGRB3 | c.1213G>C p.E405Q | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- ANKAR | c.4138del p.M1380Wfs*35 | Frame Shift Del (DEL) | VAF 65/291 reads (22%) | called by mutect2, pindel, varscan2
- ANKRD55 | c.503G>A p.W168* | Nonsense Mutation (SNP) | VAF 22/104 reads (21%) | called by muse, mutect2, varscan2
- ATF6 | c.391C>G p.P131A | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BRPF1 | c.907G>C p.E303Q | Missense Mutation (SNP) | VAF 60/189 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BRPF1 | c.3124G>C p.D1042H | Missense Mutation (SNP) | VAF 47/163 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- CAVIN4 | c.338A>T p.H113L | Missense Mutation (SNP) | VAF 56/159 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.058); called by muse, varscan2
- CCDC73 | c.2203A>C p.M735L | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- COPS9 | c.13del p.V5Wfs*25 (on ENST00000607357 / NM_001163424.2; = p.V26Wfs*35 on NM_138336.1) | Frame Shift Del (DEL) | VAF 25/80 reads (31%) | called by mutect2, pindel, varscan2
- CTBS | c.197G>A p.G66E | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- GAS2L3 | c.1030G>C p.E344Q | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- GOLGA4 | c.5129G>T p.R1710I | Missense Mutation (SNP) | VAF 53/143 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- HADHA | c.1555_1556insTTTCCA p.S518_K519insIS | In Frame Ins (INS) | VAF 34/146 reads (23%) | called by mutect2, pindel, varscan2
- HMMR | c.1847A>G p.E616G | Missense Mutation (SNP) | VAF 82/247 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- HNRNPF | c.876C>G p.H292Q | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- HRG | c.268G>C p.E90Q | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- HTR5A | c.152del p.V51Gfs*46 | Frame Shift Del (DEL) | VAF 16/66 reads (24%) | called by mutect2, pindel, varscan2
- ITPR1 | c.2424G>C p.W808C (on ENST00000354582; = p.W793C on NM_002222.7) | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- MAGEL2 | c.2162G>A p.C721Y | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- MICALL1 | c.157T>A p.S53T | Missense Mutation (SNP) | VAF 59/235 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- PAN2 | c.3384G>T p.K1128N (on ENST00000425394 / NM_001127460.3; = p.K1124N on NM_014871.5) | Missense Mutation (SNP) | VAF 55/351 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PIK3C3 | c.2286dup p.G763Wfs*19 | Frame Shift Ins (INS) | VAF 12/49 reads (24%) | called by mutect2, pindel, varscan2
- PKHD1L1 | c.11122G>T p.D3708Y | Missense Mutation (SNP) | VAF 68/174 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- PRDX3 | c.487G>C p.D163H | Missense Mutation (SNP) | VAF 61/184 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCO2 | c.655G>T p.D219Y | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SFXN4 | c.139A>T p.T47S | Missense Mutation (SNP) | VAF 93/313 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLC35F3 | c.461C>A p.A154E (on ENST00000366617 / NM_001300845.1; = p.A223E on NM_173508.4) | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- SLC6A19 | c.797A>G p.D266G | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TTN | c.28691A>T p.K9564M (on ENST00000591111; = p.K8637M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/78 reads (35%) | PolyPhen benign (0.444); called by muse, mutect2, varscan2
- WBP4 | c.404A>C p.E135A | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- WDR44 | c.1879G>C p.D627H | Missense Mutation (SNP) | VAF 65/147 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- XIRP1 | c.2975C>T p.P992L | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- DSG1 | c.1341A>G p.K447= | Silent (SNP) | VAF 104/255 reads (41%) | called by muse, mutect2, varscan2
- FBN3 | c.5910C>T p.I1970= | Silent (SNP) | VAF 23/93 reads (25%) | catalogued as rs567421534, COSV54458278; called by muse, mutect2, varscan2
- MEX3C | c.480G>C p.G160= | Silent (SNP) | VAF 16/32 reads (50%) | called by muse, mutect2, varscan2
- NR1H3 | c.567C>T p.A189= | Silent (SNP) | VAF 118/187 reads (63%) | called by muse, mutect2, varscan2
- PRMT9 | c.99G>A p.E33= | Silent (SNP) | VAF 33/101 reads (33%) | called by muse, mutect2, varscan2
- SERPINA1 | c.1044G>A p.E348= | Silent (SNP) | VAF 35/90 reads (39%) | called by muse, mutect2, varscan2
- SULT2B1 | c.183C>T p.D61= (on ENST00000201586 / NM_177973.2; = p.D46= on NM_004605.2) | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as rs931741083; called by muse, mutect2, varscan2
- TNC | c.33C>A p.V11= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV60783309; called by muse, mutect2
